Surgical pathology report (de-identified scan), TCGA case TCGA-XF-A9T6, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Southern California, specimen TCGA-XF-A9T6-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY REPORT

Collected

Ordered by

Location

DIAGNOSIS:

RADICAL CYSTECTOMY WITH PELVIC LYMPH NODE DISSECTION, TOTAL HYSTERECTOMY WITH BILATERAL SALPINGO-OOPHORECTOMY AND ILEAL CONDUIT:

RIGHT DISTAL URETER (AFS):

FROZEN SECTION DIAGNOSIS:

- NO HIGH GRADE ATYPIA OR TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETER

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LEFT DISTAL URETER (BFS):

FROZEN SECTION DIAGNOSIS:

- NO HIGH GRADE ATYPIA OR TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETER

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

BLADDER, UTERUS, OVARIES AND FALLOPIAN TUBES (C):

BLADDER:

- INVASIVE POORLY DIFFERENTIATED PAPILLARY UROTHELIAL CARCINOMA (5 X 4 X 3 CM), GRADE 3-4/4, EXTENDING GROSSLY AND MICROSCOPICALLY THROUGH RIGHT LATERAL BLADDER WALL INTO PERIVESICAL SOFT TISSUE
- SINGLE FOCUS OF LYMPHOVASCULAR INVASION IDENTIFIED
- RANDOM BLADDER MUCOSA INCLUDING TRIGONE AND BLADDER NECK, NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED
- SEVERE CHRONIC CYSTITIS
- NO MALIGNANCY IDENTIFIED IN ONE RIGHT PERIVESICAL LYMPH NODE EXAMINED (0/1)
- RESECTION MARGINS, FREE OF UROTHELIAL DYSPLASIA AND MALIGNANCY

UTERUS AND CERVIX:

- CERVIX, BENIGN SQUAMOUS AND ENDOCERVICAL MUCOSA WITH CHRONIC INFLAMMATION
- ENDOMETRIUM, ATROPHY WITH BENIGN ENDOMETRIUM POLYP
- MYOMETRIUM, NO SIGNIFICANT HISTOPATHOLOGIC CHANGE
- SEROSA, NO SIGNIFICANT HISTOPATHOLOGIC CHANGE
- NO DYSPLASIA, VIRAL CYTOPATHIC EFFECT, ATYPIA OR MALIGNANCY IDENTIFIED

BILATERAL OVARIES:

- BILATERAL OVARIES, BENIGN PHYSIOLOGIC CHANGES WITH NO SIGNIFICANT HISTOPATHOLOGIC CHANGE
- NO ATYPIA OR MALIGNANCY IDENTIFIED

BILATERAL FALLOPIAN TUBES:

- RIGHT FALLOPIAN TUBE, NO SIGNIFICANT HISTOPATHOLOGIC CHANGE
- LEFT FALLOPIAN TUBE, TUBO-UTERINE ADHESIONS
- NO ATYPIA OR MALIGNANCY IDENTIFIED

RIGHT PARA CAVAL LYMPH NODES (D):

- NO MALIGNANCY IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

RIGHT COMMON ILIAC LYMPH NODES (E):

- NO MALIGNANCY IDENTIFIED IN SEVEN LYMPH NODES EXAMINED (0/7)

PRE SACRAL LYMPH NODES (F):

- NO MALIGNANCY IDENTIFIED IN FOUR LYMPH NODES EXAMINED (0/4)

RIGHT EXTERNAL ILIAC LYMPH NODES (G):

ICD-0-3

Carcinoma, urothelial papillary
Site Bladder NOS
Bladder, lateral wall
8/30/13
8/26/14

[page 2 of 6]
Collected	
Ordered by	
Location	

- NO MALIGNANCY IDENTIFIED IN SIX LYMPH NODES EXAMINED (0/6)

RIGHT LYMPH NODE OF CLOQUET (H):

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE EXAMINED (0/1)

RIGHT OBTURATOR/HYPOGASTRIC LYMPH NODES (I):

- NO MALIGNANCY IDENTIFIED IN SEVEN LYMPH NODES EXAMINED (0/7)

LEFT PARA AORTIC LYMPH NODES (J):

- NO MALIGNANCY IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)

LEFT COMMON ILIAC LYMPH NODES (K):

- NO MALIGNANCY IDENTIFIED IN SIX LYMPH NODES EXAMINED (0/6)

LEFT LYMPH NODE OF CLOQUET (L):

- BENIGN FIBROUS ADIPOSE TISSUE, FREE OF MALIGNANCY
- NO LYMPH NODES IDENTIFIED (0/0) [TOTALLY SUBMITTED]

LEFT EXTERNAL ILIAC LYMPH NODES (M):

- NO MALIGNANCY IDENTIFIED IN FOUR LYMPH NODES EXAMINED (0/4)

LEFT OBTURATOR/HYPOGASTRIC LYMPH NODES (N):

- NO MALIGNANCY IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)

VAGINAL APEX (O):

- BENIGN VAGINAL TISSUE INCLUDING BENIGN SQUAMOUS MUCOSA
- NO VIRAL CYTOPATHIC EFFECT, DYSPLASIA OR MALIGNANCY IDENTIFIED

RIGHT PRESACRAL LYMPH NODES (P):

- NO MALIGNANCY IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)

LEFT PRESACRAL LYMPH NODES (Q):

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE EXAMINED (0/1)

PROXIMAL LEFT URETER (R):

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

RIGHT PROXIMAL URETER (S):

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LYMPH NODE SUMMARY: NO MALIGNANCY IDENTIFIED IN TOTAL OF 48 LYMPH NODES
EXAMINED (0/48)

PATHOLOGIC TNM STAGE: pT3bN0MX

COMMENT:

Representative sections of invasive carcinoma are submitted for p53 assay by immunohistology, results of which will be issued in an addendum.

SPECIMEN SOURCE:

AFS: "Rt distal ureter"

[page 3 of 6]
Collected:

Ordered by:

Location:

BFS: "Lt distal ureter"
C: "Bladder, uterus, ovaries"
D: "Right para caval LN"
E: "Right common iliac LN"
F: "Pre sacral LN"
G: "Rt external iliac LN"
H: "Rt lymph nodes of Cloquet"
I: "Rt obturator/hypogastric"
J: "Lt para aortic lymph nodes"
K: "Lt common iliac lymph nodes"
L: "Lt lymph node of Cloquet"
M: "Lt ext iliac lymph nodes"
N: "Lt obturator/hypogastric lymph nodes"
O: "Vaginal apex"
P: "Rt presciatic lymph nodes"
Q: "Lt presciatic lymph nodes"
R: "Proximal left ureter"
S: "Rt proximal ureter"

CLINICAL INFORMATION:

Pre-Op Dx: Prostate cancer

Post-Op Dx: Same

GROSS EXAMINATION:

A: The specimen is received fresh from the O.R. and labeled "Rt distal ureter". It consists of a portion of ureter measuring 0.5 cm in length and 0.4 cm in diameter. The specimen is entirely submitted for frozen section in AFS.

B: The specimen is received fresh from the O.R. and labeled "Lt distal ureter". It consists of a portion of ureter measuring 0.4 cm in length and 0.4 cm in diameter. The specimen is entirely submitted for frozen section in cassette BFS.

C: The specimen is received fresh from the O.R. and labeled "Bladder, uterus, ovaries". It consists of a cystectomy specimen with attached uterus, bilateral fallopian tubes and ovaries. Overall, the specimen measures 20.5 x 14 x 5.5 cm. Peritoneum attached posteriorly measures 18 x 12 x 0.1 cm and appears smooth and glistening with no involvement by tumor. The overlying perivesical fat (resection margin) is inked black and the specimen is opened along the anterior aspect of the bladder to reveal a polypoid exophytic mass involving the right lateral wall, close to the right ureterovesical junction and compressing the right intramural ureter. The mass measures 5 x 4 x 3 cm and grossly invades through the wall (depth of invasion 2 cm) into perivesical fat but not extending to the inked surgical resection margin. The uninvolved bladder wall measures 1 cm in thickness. The remaining bladder mucosa appears unremarkable with no other lesions or masses being identified. Bilateral ureterovesical junctions are identified and are patent. The ureters are then opened. The right attached ureter measures 9 cm in length and 0.5 cm in circumference and appears unremarkable, and the left attached ureter measures 8 cm in length and 0.5 cm in circumference and appears unremarkable. The uterus is symmetrical and measures 7 x 4.5 x 2 cm, and the serosal surface is smooth and glistening. The exocervix measures 4 cm in diameter with a slit-like os measuring 1.4 cm. The exocervical mucosal surface is smooth and glistening with no gross abnormality. The uterus is bivalved revealing endometrium that is tan-yellow in color appearing atrophic. A small polypoid lesion on the anterior aspect of the endometrium measures 0.7 cm. The myometrium ranges between 0.8 and 1 cm in thickness and appears unremarkable. The right ovary measures 2 x 0.8 and 0.5 cm and appears unremarkable. The left ovary measures 1.5 x 0.8 x 0.6 cm and appears unremarkable. The right fallopian tube measures 5 cm in length and ranges between 0.3 and 0.6 cm in diameter and appears unremarkable. The left fallopian tube measures 4 cm in length and ranges between 0.3 and 0.5 cm in diameter, with a focal tubal uterine adhesion that measures 0.6 cm with multiple firm adjacent nodules

[page 4 of 6]
Collected by:	
Ordered by:	
Location:	

ranging between 0.3 and 0.7 cm in diameter. Representative sections are submitted in 26 cassettes.

D: The specimen is received in formalin and labeled "Right para caval LN". It consists of multiple irregular fragments of fibroadipose tissue measuring 1 x 0.7 x 0.5 cm in aggregate. The specimen is entirely submitted in one cassette.

E: The specimen is received in formalin and labeled "Right common iliac LN". It consists of one irregular segment of fibroadipose tissue measuring 2.5 x 1 x 0.5 cm. The specimen is entirely submitted in two cassettes.

F: The specimen is received in formalin and labeled "Pre sacral LN". It consists of one irregular segment of fibroadipose tissue measuring 2.5 x 2 x 1 cm. The specimen is entirely submitted in three cassettes.

G: The specimen is received in formalin and labeled "Rt external iliac LN". It consists of multiple irregular fragments of fibroadipose tissue measuring 4 x 3 x 1 cm in aggregate. The specimen is entirely submitted in five cassettes.

H: The specimen is received in formalin and labeled "Rt lymph nodes of Cloquet". It consists of one irregular segment of fibroadipose tissue measuring 1.5 x 0.5 x 0.4 cm. The specimen is entirely submitted in one cassette.

I: The specimen is received in formalin and labeled "Rt obturator/hypogastric". It consists of multiple irregular fragments of fibroadipose tissue measuring 3 x 1.5 x 0.7 cm in aggregate. The specimen is entirely submitted in three cassettes.

J: The specimen is received in formalin and labeled "Lt para aortic lymph nodes". It consists of one irregular segment of fibroadipose tissue measuring 1.5 x 1 x 0.3 cm. The specimen is entirely submitted in one cassette.

K: The specimen is received in formalin and labeled "Lt common iliac lymph nodes". It consists of multiple irregular fragments of fibroadipose tissue measuring 2.5 x 1.5 x 0.5 cm in aggregate. The specimen is entirely submitted in two cassettes.

L: The specimen is received in formalin and labeled "Lt lymph node of Cloquet". It consists of one irregular segment of fibroadipose tissue measuring 1.5 x 1 x 0.5 cm. The specimen is entirely submitted in one cassette.

M: The specimen is received in formalin and labeled "Lt ext iliac lymph nodes". It consists of multiple irregular fragments of fibroadipose tissue measuring 2 x 1.5 x 1 cm in aggregate. The specimen is entirely submitted in five cassettes.

N: The specimen is received in formalin and labeled "Lt obturator/hypogastric lymph nodes". It consists of multiple irregular fragments of fibroadipose tissue measuring 3 x 2 x 1 cm in aggregate. The specimen is entirely submitted in four cassettes.

O: The specimen is received in formalin and labeled "Vaginal apex". It consists of one irregular segment of mucosal tissue with attached soft tissue measuring 2 x 1 x 0.5 cm. The mucosal surface appears unremarkable. The soft tissue is inked black. The specimen is entirely submitted in one cassette.

P: The specimen is received in formalin and labeled "Rt presciatic lymph nodes". It consists of multiple irregular fragments of fibroadipose tissue measuring 1.5 x 1 x 0.5 cm in aggregate. The specimen is entirely submitted in one cassette.

Q: The specimen is received in formalin and labeled "Lt presciatic lymph nodes". It consists of multiple irregular fragments of fibroadipose tissue measuring 2 x 1 x 0.7 cm in aggregate. The specimen is entirely submitted in two cassettes.

[page 5 of 6]
Collected

Ordered by

Location

R: The specimen is received in formalin and labeled "Proximal left ureter". It consists of a small segment of ureter measuring 0.3 cm in length and 0.2 cm in diameter. The specimen is entirely submitted in one cassette.

S: The specimen is received in formalin and labeled "Rt proximal ureter". It consists of a segment of ureter measuring 0.3 cm in length and 0.2 cm in diameter. The specimen is entirely submitted in one cassette.

SECTIONS:

AFS: frozen section, right distal ureter
BFS: frozen section, left distal ureter
C1: bladder, uterus, ovaries; apical urethral margin
C2: anterior bladder wall
C3: right lateral wall
C4: posterior wall
C5: dome
C6: left lateral wall
C7: left ureterovesical junction
C8: right ureterovesical junction
C9: trigone
C10-15: representative sections of tumor
C16: anterior exo and endocervix
C17: anterior endometrium
C18: posterior exo and endocervix
C19: posterior endometrium
C20: anterior endometrial polyp
C21: right ovary and tube
C22: left ovary and tube
C23: left tube adhesion
C24: left tube serosal nodules
C25: right perivesical fat for possible lymph nodes
C26: left perivesical fat for possible lymph nodes
D: right paracaval lymph nodes - all embedded
E1,2: right common iliac lymph nodes - all embedded (E2 - one bisected lymph node)
F1-3: presacral lymph nodes - all embedded
G1-5: right external iliac lymph nodes - all embedded (G3-one single lymph node, G5-one single lymph node)
H: right lymph node of Cloquet
I1-3: right obturator/hypogastric - all embedded
J: left para-aortic lymph nodes - all embedded
K1,2: left common iliac lymph nodes - all embedded (K2 - one bisected lymph node)
L: left lymph node of Cloquet - all embedded
M1-5: left external iliac lymph nodes - all embedded (M3 - one bisected lymph node and M4, M5 - one trisected lymph node)
N1-4: left obturator/hypogastric lymph nodes - all embedded (N3, N4 - one trisected lymph node)
O: vaginal apex - all embedded
P: right presciatic lymph nodes - all embedded
Q: left presciatic lymph nodes - all embedded
R: proximal left ureter - all embedded
S: right proximal ureter - all embedded

[page 6 of 6]
Collected

Ordered by

Location

INTRAOPERATIVE FROZEN CONSULTATION:

AFS: Right distal ureter:

- no high grade atypia or tumor identified

BFS: Left distal ureter:

- no high grade atypia or tumor identified

MICROSCOPIC EXAMINATION:

AFS-BFS: See final microscopic-diagnosis.

C: Sections of the bladder show a deeply invasive poorly differentiated papillary urothelial carcinoma (C10-15) that extends through the entire wall into perivesical fat (C10,12,13,15). A single focus of vascular invasion is seen (C12). Resection margins are free of malignancy. There is no associated in situ carcinoma (flat lesion), either adjacent to the invasive tumor or in additional random sections of the bladder mucosa.

D-S: See final microscopic-diagnosis.

Source: NCI Genomic Data Commons file e0d5c629-15da-4aeb-a7b1-f9281504764b (TCGA-XF-A9T6.84E24E42-02F8-471F-B8A4-B50D89056CA2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).